Somatic mutation profile of tumor specimen 0DP2CV from CCDI case PBCDAK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 1.1 years (404 days).
Specimen 0DP2CV: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cd5351ed-6915-4e85-b22b-b29518851b01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DP2CF (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbae8622-0a56-4da7-a463-a324263f18b2

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCB1 | c.1010del p.P337Rfs*100 (on ENST00000263121; = p.P383Rfs*100 on NM_003073.5) | Frame Shift Del (DEL) | VAF 270/447 reads (60%) | catalogued as COSV51955921; called by mutect2, pindel, varscan2
- MAGIX | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 32/695 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); called by muse, mutect2
- KRT25 | c.810G>A p.A270= | Silent (SNP) | VAF 503/1389 reads (36%) | catalogued as COSV100379948, COSV56446033; called by muse, mutect2, varscan2
